Somatic mutation profile of tumor specimen TCGA-ZG-A9L5-01A (aliquot TCGA-ZG-A9L5-01A-12D-A41K-08) from TCGA case TCGA-ZG-A9L5, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 58.3 years (21,293 days).
Specimen TCGA-ZG-A9L5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bee7b044-688c-447c-a80f-9515cecc16e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZG-A9L5-10A (Blood Derived Normal), aliquot TCGA-ZG-A9L5-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/764a3a8c-3c3d-44d6-b05c-a553162fd675

The open-access MAF lists 56 somatic variants for this specimen: 43 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 12, Nonsense Mutation 3, Frame Shift Del 2, Splice Region 1, Frame Shift Ins 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD14A-ACY1 | c.851A>C p.D284A | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.522); catalogued as COSV99865562; called by muse, mutect2, varscan2
- ADRA1A | c.104del p.G35Afs*12 | Frame Shift Del (DEL) | VAF 67/95 reads (71%) | catalogued as rs752308205; called by mutect2, varscan2
- ALAS1 | c.1711C>T p.R571W | Missense Mutation (SNP) | VAF 51/229 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778599796, COSV100050463; called by muse, mutect2, varscan2
- ANKAR | c.379G>T p.D127Y | Missense Mutation (SNP) | VAF 53/84 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99854581; called by muse, mutect2, varscan2
- AZIN2 | c.1214A>C p.H405P | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99613728; called by muse, mutect2, varscan2
- CAMTA1 | c.2347G>A p.V783M | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs370719100; called by muse, mutect2
- CFHR5 | c.484A>T p.K162* | Nonsense Mutation (SNP) | VAF 70/121 reads (58%) | catalogued as COSV99889577; called by muse, mutect2, varscan2
- CUL5 | c.2107G>C p.E703Q | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV101263745; called by muse, mutect2
- DDB1 | c.3245C>A p.T1082K | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV100074827; called by muse, mutect2, varscan2
- DDX50 | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1454752786, COSV101007305; called by muse, mutect2, varscan2
- DYNC1I1 | c.862C>G p.R288G | Missense Mutation (SNP) | VAF 9/280 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100269140, COSV61456238; called by muse, mutect2
- DYNC2H1 | c.695A>G p.D232G | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1326645165, COSV100519577; called by muse, mutect2, varscan2
- EDA | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101000158; called by muse, mutect2
- EIF4G3 | c.1211C>A p.A404D | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.029); catalogued as COSV99945415; called by muse, mutect2, varscan2
- HSD17B2 | c.1137G>T p.M379I | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV99556800; called by muse, mutect2, varscan2
- KMO | c.377C>A p.P126H | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1270065039, COSV100844815; called by muse, mutect2, varscan2
- KMT2D | c.10639C>T p.R3547C | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56424101; called by muse, mutect2
- KRTAP9-4 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV100484947; called by muse, mutect2, varscan2
- LPO | c.961C>A p.R321S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV51860612, COSV99229266; called by muse, varscan2
- MELK | c.859G>A p.V287I | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs374744271, COSV53197392; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYH2 | c.648+2T>A p.X216_splice | Splice Site (SNP) | VAF 4/51 reads (8%) | catalogued as COSV55435823; called by muse, mutect2
- OBSCN | c.4066G>A p.A1356T | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.06); catalogued as COSV52740366; called by muse, mutect2, varscan2
- OR10Z1 | c.272C>A p.A91D | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1452793916, COSV100779077; called by muse, mutect2, varscan2
- OR51E2 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752200411, COSV101211338; called by mutect2, varscan2
- OR9I1 | c.240G>T p.Q80H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); catalogued as COSV100110451; called by muse, mutect2, varscan2
- PCDHB8 | c.1539C>G p.H513Q | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as COSV99177303; called by muse, mutect2, varscan2
- PTER | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs183203379, COSV100126824; called by muse, mutect2, varscan2
- RARB | c.505A>T p.T169S (on ENST00000383772 / NM_001290216.2; = p.T162S on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100412814; called by muse, mutect2, varscan2
- RPS4Y2 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 60/67 reads (90%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.552); catalogued as COSV99978434; called by muse, mutect2, varscan2
- SLC2A12 | c.843A>G p.I281M | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV99260484; called by muse, mutect2, varscan2
- SLC6A1 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as COSV55119348, COSV99823146; called by muse, mutect2
- SNX19 | c.1768C>T p.Q590* | Nonsense Mutation (SNP) | VAF 31/61 reads (51%) | catalogued as COSV99773544; called by muse, mutect2, varscan2
- SPHKAP | c.4090G>C p.V1364L | Missense Mutation (SNP) | VAF 48/74 reads (65%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs1211931782, COSV100764508; called by muse, mutect2, varscan2
- SPTA1 | c.5605G>T p.A1869S | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as COSV63749974; called by muse, mutect2, varscan2
- STOX2 | c.885G>A p.W295* | Nonsense Mutation (SNP) | VAF 4/11 reads (36%) | catalogued as COSV100409180; called by muse, mutect2
- SYT9 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as COSV100609007; called by muse, mutect2, varscan2
- TAF1L | c.2647C>G p.L883V | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV99645325; called by muse, mutect2
- TFPT | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 52/82 reads (63%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.226); catalogued as rs749420696, COSV99500073; called by muse, mutect2, varscan2
- TTN | c.15628G>A p.V5210I (on ENST00000591111; = p.V4283I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | PolyPhen benign (0.001); catalogued as rs1334663895, COSV100627133; called by muse, mutect2, varscan2
- APOBEC2 | c.242dup p.Q82Pfs*12 | Frame Shift Ins (INS) | VAF 17/59 reads (29%) | called by mutect2, pindel, varscan2
- BSN | c.1908G>T p.K636N | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.091); called by muse, mutect2
- MTHFD1L | c.721del p.Q241Rfs*6 | Frame Shift Del (DEL) | VAF 27/104 reads (26%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1814+4dup | Splice Region (INS) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- AJAP1 | c.1128G>A p.T376= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs559785406, COSV100981998; called by muse, mutect2, varscan2
- AL441992.2 | c.1377C>T p.F459= | Silent (SNP) | VAF 27/221 reads (12%) | catalogued as rs1415351939, COSV100223821; called by muse, mutect2, varscan2
- CDC42BPA | c.4699A>C p.R1567= (on ENST00000334218 / NM_001366019.2; = p.R1554= on NM_003607.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV100506684; called by muse, mutect2
- CFAP46 | c.5628C>T p.G1876= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV99585458; called by muse, mutect2, varscan2
- DYRK4 | c.1461G>A p.K487= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV99157819; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1677G>A p.L559= (on ENST00000361735 / NM_015935.5; = p.L473= on NM_014955.3) | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as COSV100676023; called by muse, mutect2, varscan2
- GAK | c.3489G>T p.G1163= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as COSV100034012; called by muse, mutect2, varscan2
- MGAM | c.435C>T p.V145= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs1554457577, COSV101516531; called by muse, mutect2, varscan2
- PLBD2 | c.1491C>G p.P497= | Silent (SNP) | VAF 309/497 reads (62%) | catalogued as COSV99785486; called by muse, mutect2, varscan2
- SLITRK2 | c.240C>T p.N80= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV59424824; called by muse, mutect2
- SPTBN1 | c.3252G>A p.A1084= | Silent (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- VANGL2 | c.366G>A p.T122= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as rs767929095, COSV100925606; called by muse, mutect2, varscan2
- KRT18P55 | n.863G>A | RNA (SNP) | VAF 9/76 reads (12%) | catalogued as rs760764459; called by muse, mutect2, varscan2
